Somatic mutation profile of tumor specimen C3N-03882-01 (aliquot CPT0237760006) from CPTAC case C3N-03882, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.9 years (25,174 days).
Specimen C3N-03882-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91680298-c4f4-4c4c-b061-7012b8d58e61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03882-31 (Blood Derived Normal), aliquot CPT0237820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6947df5b-21f2-4fe1-bdc3-4895988b2c2d

The open-access MAF lists 296 somatic variants for this specimen: 197 protein-altering or splice-affecting, 55 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 55, Intron 19, RNA 10, Nonsense Mutation 10, Frame Shift Del 8, 5'Flank 7, 3'UTR 4, Splice Region 3, 5'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 226/289 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 148/273 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as rs1173711960; called by muse, mutect2, varscan2
- ABCC10 | c.1270G>T p.V424L (on ENST00000372530 / NM_001198934.2; = p.V381L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/167 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99766924; called by muse, mutect2, varscan2
- ABCC8 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 123/332 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1254230359; called by muse, mutect2, varscan2
- ACTL7B | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs139846981, COSV65928037; called by muse, mutect2, varscan2
- ALG14 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 77/104 reads (74%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as rs1434287085; called by muse, mutect2, varscan2
- APC | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.246); catalogued as rs756336949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATG2A | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 118/424 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1442371432; called by muse, mutect2, varscan2
- BRCA1 | c.4893T>A p.S1631R | Missense Mutation (SNP) | VAF 124/289 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs80356850; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- CDC42EP4 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 157/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776312011, COSV100231735; called by muse, mutect2, varscan2
- COBL | c.3764G>C p.R1255T | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV54338714; called by muse, mutect2, varscan2
- CSMD3 | c.5510G>C p.G1837A (on ENST00000297405 / NM_001363185.1; = p.G1733A on NM_052900.3) | Missense Mutation (SNP) | VAF 121/247 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52309266; called by muse, mutect2, varscan2
- DDX20 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 182/231 reads (79%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs1405821088; called by muse, mutect2, varscan2
- DUT | c.260del p.G87Efs*68 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs1319818877; called by mutect2, pindel
- FAP | c.270G>T p.L90F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV51868316, COSV99502296; called by muse, mutect2, varscan2
- FAT2 | c.3140C>A p.S1047* | Nonsense Mutation (SNP) | VAF 69/337 reads (20%) | catalogued as COSV55823994; called by muse, mutect2, varscan2
- FCRL2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV63833673; called by muse, mutect2, varscan2
- FMNL3 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 129/242 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370114728; called by muse, mutect2, varscan2
- FNDC1 | c.5286C>T p.G1762= | Splice Region (SNP) | VAF 62/79 reads (78%) | catalogued as rs531683818, COSV51936066; called by muse, mutect2, varscan2
- FRY | c.4171C>T p.R1391W | Missense Mutation (SNP) | VAF 325/421 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs773635841, COSV66564689; called by muse, mutect2, varscan2
- FSIP2 | c.16178G>A p.R5393K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539000265; called by muse, mutect2, varscan2
- GABRR3 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.076); catalogued as rs774171414, COSV101512354; called by muse, mutect2, varscan2
- GLYAT | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs370369666, COSV99557217; called by muse, mutect2, varscan2
- HAPLN4 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV52270328; called by muse, mutect2, varscan2
- HGF | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 191/333 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55945692; called by muse, mutect2, varscan2
- IL16 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as COSV57260094; called by muse, mutect2, varscan2
- KCNA4 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs866978411, COSV100069091, COSV60256000; called by muse, mutect2, varscan2
- MRGPRD | c.120C>A p.C40* | Nonsense Mutation (SNP) | VAF 312/455 reads (69%) | catalogued as rs148272462; called by muse, mutect2, varscan2
- MUC17 | c.6589G>A p.E2197K | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs1414327389, COSV60289413; called by muse, mutect2, varscan2
- MYF6 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 154/362 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV57352844, COSV99953022; called by muse, mutect2, varscan2
- MYMK | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs758327852; called by muse, mutect2, varscan2
- NELL2 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61582318; called by muse, mutect2, varscan2
- NIPAL1 | c.1045A>T p.I349F | Missense Mutation (SNP) | VAF 192/219 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1035006940; called by muse, mutect2, varscan2
- NLGN3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 118/139 reads (85%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100704586, COSV62444159; called by muse, mutect2, varscan2
- NOTCH2 | c.6892C>T p.R2298W | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1270274564, COSV56685860; called by muse, mutect2
- NOVA1 | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 266/338 reads (79%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.776); catalogued as COSV57488713; called by mutect2, varscan2
- NRP2 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55934450; called by muse, mutect2, varscan2
- NUFIP1 | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 85/116 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs199660590; called by muse, mutect2, varscan2
- OR4K5 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60002427, COSV60004795; called by muse, mutect2
- OR9A4 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs782620469; called by muse, mutect2, varscan2
- OTOL1 | c.390G>T p.L130F | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.123); catalogued as COSV60006187; called by muse, mutect2, varscan2
- PAX6 | c.331del p.V111Sfs*13 | Frame Shift Del (DEL) | VAF 103/359 reads (29%) | catalogued as CD973066; called by mutect2, pindel, varscan2
- PCDH19 | c.2479C>T p.R827C (on ENST00000373034 / NM_001184880.2; = p.R780C on NM_020766.3) | Missense Mutation (SNP) | VAF 221/252 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs773732791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB1 | c.3554C>G p.S1185C | Missense Mutation (SNP) | VAF 193/485 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV62069688; called by muse, mutect2, varscan2
- PLCL1 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV70883685; called by muse, mutect2, varscan2
- PLEC | c.12107G>T p.R4036L (on ENST00000322810 / NM_201380.4; = p.R3926L on NM_000445.5) | Missense Mutation (SNP) | VAF 235/736 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs782307503, COSV59610919; called by muse, mutect2, varscan2
- PMS1 | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1024781270; called by muse, mutect2, varscan2
- PNLIPRP2 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 117/207 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs559093127; called by muse, mutect2, varscan2
- PNPLA6 | c.2435C>T p.P812L (on ENST00000414982 / NM_001166111.2; = p.P764L on NM_006702.5) | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs1009954378, COSV99652954; called by muse, mutect2, varscan2
- PPP1R3A | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 89/137 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV52875600; called by muse, mutect2, varscan2
- PRDM9 | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57005109; called by muse, mutect2, varscan2
- RAPSN | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs528442857, COSV54085700; called by muse, mutect2, varscan2
- RNF167 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs760638375, COSV99337215; called by muse, mutect2, varscan2
- SLC34A1 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 309/650 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774934910, COSV60999079; called by muse, mutect2, varscan2
- SPDYE4 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 94/130 reads (72%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs371237439, COSV60905978; called by muse, mutect2, varscan2
- TMEM237 | c.761A>G p.Q254R (on ENST00000409883 / NM_001044385.3; = p.Q246R on NM_152388.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as rs777686525; called by muse, mutect2, varscan2
- TRIP11 | c.2304T>G p.N768K | Missense Mutation (SNP) | VAF 165/254 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV50953011; called by muse, mutect2, varscan2
- TTN | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | PolyPhen probably damaging (0.954); catalogued as COSV60376849; called by muse, mutect2, varscan2
- UGT3A1 | c.1498A>C p.M500L | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99954669; called by muse, mutect2, varscan2
- USF3 | c.3064C>G p.L1022V | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100325680; called by muse, mutect2, varscan2
- YBX2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 173/237 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs755423340; called by muse, mutect2, varscan2
- ZC3H12B | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs748596450, COSV59050811; called by mutect2, varscan2
- ZFHX4 | c.1081C>A p.R361S | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.994); catalogued as COSV51491941; called by muse, mutect2, varscan2
- ZFP28 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs746484114; called by muse, mutect2, varscan2
- ADGRE2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 123/488 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- AFF3 | c.1669G>C p.A557P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALS2 | c.4036A>T p.T1346S | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.075); called by muse, varscan2
- ANGPT2 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ANKRD30BL | c.104A>T p.H35L | Missense Mutation (SNP) | VAF 168/304 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ANKRD36C | c.2024G>A p.G675D | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ANO5 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 79/253 reads (31%) | called by muse, mutect2, varscan2
- ATP2B4 | c.2765G>A p.G922D | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- B3GNT3 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- C6 | c.1819C>A p.Q607K | Missense Mutation (SNP) | VAF 113/320 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- C9orf135 | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CADPS2 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 133/270 reads (49%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC141 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CCDC7 | c.2651G>T p.G884V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 169/437 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNL1 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 127/221 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CDH8 | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CKS2 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CLEC2L | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CLK3 | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- COL6A6 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CPB1 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DIP2A | c.2353A>T p.R785W | Missense Mutation (SNP) | VAF 181/228 reads (79%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DLAT | c.1133C>A p.T378K | Missense Mutation (SNP) | VAF 130/171 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- DMBT1 | c.3136G>C p.A1046P (on ENST00000338354 / NM_001377530.1; = p.A547P on NM_004406.3) | Missense Mutation (SNP) | VAF 182/731 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, varscan2
- DOCK4 | c.3980C>A p.P1327Q | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DRC1 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 59/241 reads (24%) | called by muse, mutect2, varscan2
- EML6 | c.3177G>C p.L1059F | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ERG | c.944G>A p.S315N (on ENST00000398919 / NM_001243428.1; = p.S291N on NM_004449.4) | Missense Mutation (SNP) | VAF 76/90 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ERP44 | c.670T>A p.L224M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM122A | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAP | c.576A>G p.I192M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- FBN2 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 149/280 reads (53%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FOLR3 | c.169-7C>A | Splice Region (SNP) | VAF 247/1406 reads (18%) | called by muse, mutect2, varscan2
- FOXRED2 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 151/271 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- FSIP2 | c.14494G>A p.E4832K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- G2E3 | c.1724A>G p.Y575C | Missense Mutation (SNP) | VAF 75/102 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GFPT1 | c.1253T>C p.L418P (on ENST00000357308 / NM_001244710.2; = p.L400P on NM_002056.4) | Missense Mutation (SNP) | VAF 101/375 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNPAT | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 110/312 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- GRIN2D | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSE1 | c.3589C>T p.R1197* | Nonsense Mutation (SNP) | VAF 76/219 reads (35%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.328_329dup p.A111Rfs*7 | Frame Shift Ins (INS) | VAF 112/283 reads (40%) | called by mutect2, pindel, varscan2
- ITGA3 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- KBTBD3 | c.480A>G p.I160M | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KHDRBS3 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- KIZ | c.1909A>T p.N637Y | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LAMC3 | c.4618G>C p.E1540Q | Missense Mutation (SNP) | VAF 319/814 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LEMD3 | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 75/172 reads (44%) | called by muse, mutect2, varscan2
- LGI1 | c.1597C>A p.R533S | Missense Mutation (SNP) | VAF 98/168 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- MAP4 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 133/181 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MAP4 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- MAP4K3 | c.1282A>T p.K428* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- MCAM | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.33); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MGST3 | c.117+7G>T | Splice Region (SNP) | VAF 149/305 reads (49%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.760A>C p.K254Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, varscan2
- MRPS9 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MTMR4 | c.3230A>G p.D1077G | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MUC16 | c.29621C>G p.S9874* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- MYCN | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- NDUFAF5 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NSD3 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR14C36 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- OR2C3 | c.296_297del p.V99Gfs*23 | Frame Shift Del (DEL) | VAF 80/310 reads (26%) | called by pindel, varscan2
- OR2T1 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPOLA | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PARD3 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 150/353 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCDHA3 | c.1426A>G p.T476A | Missense Mutation (SNP) | VAF 425/890 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PCDHB14 | c.39del p.V14Ffs*2 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- PIBF1 | c.1580_1584del p.L527Hfs*3 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.1882A>G p.T628A | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- PKHD1L1 | c.3835G>C p.G1279R | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLXNA4 | c.3206A>G p.Q1069R | Missense Mutation (SNP) | VAF 132/255 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PREX1 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCH2 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 113/148 reads (76%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PTGS2 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PUS10 | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PXDN | c.1157A>T p.D386V | Missense Mutation (SNP) | VAF 112/604 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RASA1 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RELN | c.4664T>A p.L1555Q | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RHOV | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 120/228 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- RPL22L1 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 55/788 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2
- RTCB | c.21T>A p.D7E | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.5179G>T p.V1727F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SACS | c.7922G>T p.G2641V | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SALL1 | c.2632del p.A878Qfs*8 | Frame Shift Del (DEL) | VAF 55/152 reads (36%) | called by mutect2, pindel, varscan2
- SCARF2 | c.1202A>G p.H401R | Missense Mutation (SNP) | VAF 127/244 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SCN7A | c.2377C>G p.H793D | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SERPINF2 | c.387_418del p.L129Ffs*61 | Frame Shift Del (DEL) | VAF 58/253 reads (23%) | called by mutect2, pindel
- SLC12A1 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A9 | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 174/449 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC35C1 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC5A1 | c.193A>G p.M65V | Missense Mutation (SNP) | VAF 305/591 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC6A14 | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLCO4C1 | c.1408G>C p.V470L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SNRPN | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SORCS1 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SSTR2 | c.8_25del p.M3_L8del | In Frame Del (DEL) | VAF 60/177 reads (34%) | called by mutect2, pindel, varscan2
- STAG1 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 115/207 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SULT1C4 | c.92C>G p.T31S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SVOPL | c.1327G>T p.A443S (on ENST00000419765; = p.A291S on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/324 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- SYN3 | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TADA2A | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TBC1D30 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCL1B | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 319/377 reads (85%) | called by muse, mutect2, varscan2
- TDRD9 | c.3997A>G p.R1333G | Missense Mutation (SNP) | VAF 44/540 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- TEX29 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, varscan2
- TMEM132D | c.2838A>T p.R946S | Missense Mutation (SNP) | VAF 162/421 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM169 | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 305/482 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TNKS2 | c.3433G>C p.E1145Q | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNRC6B | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TRAV1-1 | c.6G>T p.W2C | Missense Mutation (SNP) | VAF 418/462 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TRPM1 | c.4222G>C p.E1408Q | Missense Mutation (SNP) | VAF 131/485 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TTC21A | c.2860C>A p.Q954K | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR2 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- URGCP | c.2425del p.T809Rfs*37 (on ENST00000453200 / NM_001077663.3; = p.T800Rfs*37 on NM_017920.4) | Frame Shift Del (DEL) | VAF 79/211 reads (37%) | called by mutect2, pindel, varscan2
- USP13 | c.2477G>A p.C826Y | Missense Mutation (SNP) | VAF 172/209 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP28 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 91/123 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- USP42 | c.614C>G p.T205S | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- VGLL2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDFY3 | c.6574+1G>A p.X2192_splice | Splice Site (SNP) | VAF 48/68 reads (71%) | called by muse, mutect2, varscan2
- WDR17 | c.2539A>T p.K847* | Nonsense Mutation (SNP) | VAF 103/150 reads (69%) | called by muse, mutect2, varscan2
- WDR33 | c.3546G>T p.W1182C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- XIRP2 | c.6688C>G p.Q2230E (on ENST00000628543; = p.Q2405E on NM_152381.6) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- ZNF423 | c.3497A>G p.Q1166R (on ENST00000563137 / NM_001379286.1; = p.Q1158R on NM_015069.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, varscan2
- ZNF467 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF630 | c.1112G>C p.R371T | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF638 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF644 | c.2510C>A p.T837N | Missense Mutation (SNP) | VAF 105/145 reads (72%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF658 | c.2491T>C p.C831R | Missense Mutation (SNP) | VAF 232/567 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF687 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF804A | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF98 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- AHNAK | c.14949G>A p.G4983= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- ASPM | c.8497C>T p.L2833= | Silent (SNP) | VAF 78/234 reads (33%) | called by muse, mutect2, varscan2
- ASTN1 | c.2148G>A p.R716= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs1261325201; called by muse, mutect2, varscan2
- ATP6V0D2 | c.390C>T p.H130= | Silent (SNP) | VAF 78/191 reads (41%) | catalogued as rs768611666; called by muse, mutect2, varscan2
- BCAS1 | c.948C>T p.T316= | Silent (SNP) | VAF 159/370 reads (43%) | catalogued as COSV101005991; called by muse, mutect2, varscan2
- C8orf34 | c.810T>A p.I270= | Silent (SNP) | VAF 67/106 reads (63%) | called by muse, mutect2, varscan2
- CFAP69 | c.2271A>G p.G757= | Silent (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- CHRNA4 | c.753C>T p.I251= | Silent (SNP) | VAF 269/663 reads (41%) | catalogued as rs121912254, COSV64721137; ClinVar: not provided; called by muse, mutect2, varscan2
- CIT | c.2986C>A p.R996= | Silent (SNP) | VAF 189/428 reads (44%) | catalogued as rs771984153, COSV55861202; called by muse, mutect2, varscan2
- CNTNAP5 | c.3676C>A p.R1226= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV70474426; called by muse, mutect2, varscan2
- CTSA | c.1302G>T p.G434= | Silent (SNP) | VAF 276/666 reads (41%) | called by muse, mutect2, varscan2
- DACH1 | c.1440G>A p.E480= (on ENST00000619232 / NM_001366712.1; = p.E428= on NM_080759.6) | Silent (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- DIPK1C | c.1101C>A p.V367= | Silent (SNP) | VAF 163/212 reads (77%) | called by muse, mutect2, varscan2
- DPY19L3 | c.948C>T p.I316= | Silent (SNP) | VAF 95/179 reads (53%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.408G>T p.R136= | Silent (SNP) | VAF 59/590 reads (10%) | called by muse, mutect2, varscan2
- EIF3L | c.1590C>T p.I530= | Silent (SNP) | VAF 82/167 reads (49%) | catalogued as rs369820470, COSV65951784; called by muse, mutect2, varscan2
- FNDC7 | c.21A>T p.T7= | Silent (SNP) | VAF 69/96 reads (72%) | called by muse, mutect2, varscan2
- FRMD1 | c.1287G>T p.P429= | Silent (SNP) | VAF 95/132 reads (72%) | called by muse, mutect2, varscan2
- GIMAP6 | c.570G>C p.V190= | Silent (SNP) | VAF 195/251 reads (78%) | called by muse, mutect2, varscan2
- GPI | c.1308G>T p.L436= | Silent (SNP) | VAF 38/648 reads (6%) | catalogued as COSV100731565; called by muse, mutect2
- HDAC6 | c.1752C>T p.G584= | Silent (SNP) | VAF 127/148 reads (86%) | catalogued as rs782108376; called by muse, mutect2, varscan2
- HOXD10 | c.315C>A p.T105= | Silent (SNP) | VAF 100/165 reads (61%) | catalogued as COSV50906340; called by muse, mutect2, varscan2
- ITIH6 | c.399C>T p.S133= | Silent (SNP) | VAF 170/196 reads (87%) | catalogued as rs746382212; called by muse, mutect2, varscan2
- IZUMO3 | c.573T>A p.A191= (on ENST00000543880 / NM_001365008.2; = p.A185= on NM_001271706.1) | Silent (SNP) | VAF 29/43 reads (67%) | called by muse, mutect2, varscan2
- KAT14 | c.1476A>G p.K492= | Silent (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- KRTAP2-1 | c.255G>A p.T85= | Silent (SNP) | VAF 106/459 reads (23%) | called by muse, mutect2, varscan2
- LILRA6 | c.1347C>T p.I449= | Silent (SNP) | VAF 76/113 reads (67%) | catalogued as COSV54444383; called by muse, mutect2, varscan2
- LRRC9 | c.4042T>C p.L1348= | Silent (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- MAGEF1 | c.177G>A p.A59= | Silent (SNP) | VAF 66/292 reads (23%) | catalogued as rs1327190076, COSV100510898, COSV58633728; called by muse, mutect2, varscan2
- MKRN3 | c.1348C>A p.R450= | Silent (SNP) | VAF 131/259 reads (51%) | catalogued as COSV58808600, COSV58811332; called by muse, mutect2, varscan2
- MRPS26 | c.366G>C p.A122= | Silent (SNP) | VAF 202/512 reads (39%) | catalogued as COSV55662209; called by muse, mutect2, varscan2
- OR13G1 | c.567A>C p.V189= | Silent (SNP) | VAF 43/119 reads (36%) | called by muse, mutect2, varscan2
- OR2AK2 | c.228C>A p.T76= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100823098; called by muse, mutect2
- PCDHB11 | c.1890G>A p.L630= | Silent (SNP) | VAF 290/828 reads (35%) | called by muse, mutect2, varscan2
- PCDHB15 | c.180C>A p.A60= | Silent (SNP) | VAF 72/226 reads (32%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.114C>T p.P38= | Silent (SNP) | VAF 58/232 reads (25%) | called by muse, mutect2, varscan2
- PDLIM1 | c.771G>A p.L257= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as rs1197348657; called by muse, mutect2, varscan2
- PHF3 | c.2133A>G p.K711= | Silent (SNP) | VAF 62/243 reads (26%) | catalogued as COSV99029785; called by muse, mutect2, varscan2
- PRKCSH | c.1509C>T p.L503= | Silent (SNP) | VAF 292/537 reads (54%) | called by muse, mutect2, varscan2
- PTPRD | c.3915G>A p.P1305= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as rs201090377, COSV100647752; called by muse, mutect2, varscan2
- REG3A | c.315G>A p.G105= | Silent (SNP) | VAF 96/201 reads (48%) | called by muse, varscan2
- RGL2 | c.1221G>A p.L407= | Silent (SNP) | VAF 44/210 reads (21%) | catalogued as rs1397450277; called by muse, mutect2, varscan2
- RPS6KA4 | c.501G>T p.V167= | Silent (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- RTF2 | c.612A>T p.A204= | Silent (SNP) | VAF 46/141 reads (33%) | called by muse, mutect2, varscan2
- SACS | c.7923C>T p.G2641= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs774258729; called by muse, mutect2, varscan2
- TACR3 | c.195C>T p.P65= | Silent (SNP) | VAF 78/106 reads (74%) | catalogued as rs1266132600, COSV59200784; called by muse, mutect2, varscan2
- TCL1B | c.375G>A p.E125= | Silent (SNP) | VAF 27/394 reads (7%) | called by muse, mutect2
- TGFBI | c.675C>A p.T225= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as rs886059925; ClinVar: uncertain significance; called by muse, mutect2
- TMBIM1 | c.321C>T p.S107= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs141839821, COSV51464653; called by muse, mutect2
- TMEM108 | c.1482G>A p.R494= | Silent (SNP) | VAF 106/183 reads (58%) | catalogued as rs770330869; called by muse, mutect2, varscan2
- TTC7A | c.1239A>G p.E413= | Silent (SNP) | VAF 82/367 reads (22%) | called by muse, mutect2, varscan2
- UNC5D | c.2082G>A p.A694= | Silent (SNP) | VAF 108/570 reads (19%) | catalogued as rs199531607, COSV54797287; called by muse, mutect2, varscan2
- WWTR1 | c.339C>T p.L113= | Silent (SNP) | VAF 48/275 reads (17%) | catalogued as COSV100640928; called by muse, mutect2, varscan2
- ZNF248 | c.72G>T p.L24= | Silent (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- ZNF883 | c.936G>A p.Q312= | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as COSV71309291; called by muse, mutect2, varscan2
- ABCB1 | c.1351-21C>T | Intron (SNP) | VAF 287/470 reads (61%) | called by muse, mutect2, varscan2
- AC022415.2 | c.*2815T>C | 3'UTR (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*173C>G | 3'UTR (SNP) | VAF 91/122 reads (75%) | called by muse, mutect2, varscan2
- ACAD11 | c.1689-101A>T | Intron (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- ACSL3 | c.806-212G>C | Intron (SNP) | VAF 48/59 reads (81%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1431C>T | RNA (SNP) | VAF 305/491 reads (62%) | called by muse, mutect2, varscan2
- AF186192.2 | chr8:144698975 C>T | 5'Flank (SNP) | VAF 23/67 reads (34%) | catalogued as rs951365427; called by muse, mutect2
- AL355390.1 | n.568G>A | RNA (SNP) | VAF 50/226 reads (22%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1983-122G>T | Intron (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.228G>A | RNA (SNP) | VAF 200/253 reads (79%) | called by muse, mutect2, varscan2
- C8orf31 | n.567G>A | RNA (SNP) | VAF 25/153 reads (16%) | catalogued as rs1205630338; called by muse, mutect2, varscan2
- CD34 | c.598-219G>T | Intron (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- CLEC6A | c.-11G>T | 5'UTR (SNP) | VAF 55/84 reads (65%) | catalogued as rs1034881278; called by muse, mutect2, varscan2
- EMD | c.400-29A>T | Intron (SNP) | VAF 253/294 reads (86%) | called by muse, mutect2, varscan2
- FAM27E5 | n.137G>T | RNA (SNP) | VAF 93/139 reads (67%) | called by muse, mutect2, varscan2
- FRG1BP | n.430T>A | RNA (SNP) | VAF 67/266 reads (25%) | called by muse, mutect2, varscan2
- HS1BP3 | c.406+140G>T | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- KCTD17 | c.211-504del | Intron (DEL) | VAF 59/323 reads (18%) | called by mutect2, pindel, varscan2
- LINC00671 | n.543A>G | RNA (SNP) | VAF 53/109 reads (49%) | catalogued as rs1297822581; called by muse, mutect2, varscan2
- LINC01036 | n.195T>A | RNA (SNP) | VAF 64/205 reads (31%) | called by muse, mutect2, varscan2
- LINC01118 | n.1191+464G>A | Intron (SNP) | VAF 72/142 reads (51%) | catalogued as rs1263249995; called by muse, mutect2, varscan2
- LINC01193 | n.1424C>G | RNA (SNP) | VAF 78/252 reads (31%) | called by muse, mutect2, varscan2
- MTCL1 | c.2967+214A>G | Intron (SNP) | VAF 75/322 reads (23%) | called by muse, varscan2
- NBPF22P | n.687C>A | RNA (SNP) | VAF 89/205 reads (43%) | called by muse, mutect2, varscan2
- NRG3 | c.823+1758C>A | Intron (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53596A>T | Intron (SNP) | VAF 68/189 reads (36%) | called by muse, mutect2, varscan2
- PDE4D | c.42+37774A>G | Intron (SNP) | VAF 59/80 reads (74%) | called by muse, mutect2, varscan2
- PFKM | chr12:48118526 G>A | 5'Flank (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2
- PHF7 | c.-20G>A | 5'UTR (SNP) | VAF 67/85 reads (79%) | catalogued as rs1440735156; called by muse, mutect2, varscan2
- PNCK | chrX:153674080 C>G | 5'Flank (SNP) | VAF 258/294 reads (88%) | catalogued as COSV100562326; called by muse, mutect2, varscan2
- PRKCSH | c.1175+13G>A | Intron (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- RAN | c.36+48A>G | Intron (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- RASSF4 | c.63-124G>T | Intron (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- RERG | c.62-16755T>C | Intron (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40558126 G>C | 5'Flank (SNP) | VAF 81/167 reads (49%) | called by muse, mutect2, varscan2
- SCML2P1 | chr18:6928460 G>C | 3'Flank (SNP) | VAF 62/113 reads (55%) | called by muse, mutect2, varscan2
- SNORD115-9 | chr15:25182342 G>T | 5'Flank (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- SNORD115-9 | chr15:25182474 G>T | 5'Flank (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.523-105G>T | Intron (SNP) | VAF 174/482 reads (36%) | called by muse, mutect2, varscan2
- STK32A | c.*410A>G | 3'UTR (SNP) | VAF 32/124 reads (26%) | called by muse, mutect2, varscan2
- TMEM155 | chr4:121766208 A>T | 5'Flank (SNP) | VAF 187/263 reads (71%) | called by muse, mutect2, varscan2
- TRIAP1 | c.*27G>A | 3'UTR (SNP) | VAF 26/215 reads (12%) | catalogued as rs564425873, COSV99984792, COSV99984846; called by muse, mutect2, varscan2
- Unknown | chr17:43377702 T>C | IGR (SNP) | VAF 201/529 reads (38%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+297C>G | Intron (SNP) | VAF 118/162 reads (73%) | called by muse, mutect2, varscan2
